TCGA case TCGA-5M-AATA — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: University of Sao Paulo.
https://portal.gdc.cancer.gov/cases/a9e4b6db-8b4b-4345-a4a1-d63175eb0174

Demographics
Country of residence at enrollment: Brazil.

Diagnoses (1)
1. Primary (histology not recorded by GDC). Site of resection or biopsy: Colon, NOS; Prior malignancy: no; Synchronous malignancy: No.
   Pathology details: Consistent pathology review: Yes.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-5M-AATA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 210 mg.
  Slide TCGA-5M-AATA-01A-03-TS3: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-5M-AATA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-5M-AATA-01A-31D-A40O-01): tumor purity 0.43, ploidy 3.94, whole-genome doublings 1.
